Surgical pathology report (de-identified scan), TCGA case TCGA-DS-A1OC, project TCGA-CESC (Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma), tissue source site Cedars Sinai, specimen TCGA-DS-A1OC-01A (Primary Tumor).

[page 1 of 8]
RESULTS FOR SELECTED GRID CELL, SUMMARY
Printed

By: _____

100-0-3
Carcinoma, squamous cell, NOS 8070/3
Site: cervix, NOS c53.9 3/4/11
lw

Ord #= [REDACTED]
SURGICAL PATHOLOGY

ASAP/RESULTED

Collect D/T= _____

Modifiers:

(1 of 1)

SURGICAL PATHOLOGY:

CoPath Specimen #

Source:

- A: Left External iliac lymph node \T\ obturator
- B: Left Common iliac lymph node
- C: Left Peri-aortic lymph node
- D: Right External iliac lymph node
- E: Right Obturator lymph node
- F: Right Common iliac lymph node
- G: Right Peri-aortic lymph node
- H: Recto-vaginal septum biopsy, (f/s)
- I: Uterus, Cervix \T\ ovaries

Final Diagnosis

- A. Lymph nodes, left external iliac \T\ obturator (excision);
- 2 out of 2 lymph nodes show metastatic squamous cell carcinoma
- Lymph node largest size: 4 cm in maximal dimension
- No evidence of extracapsular invasion
- B. Lymph node, common iliac (excision):
- 1 out of 1 lymph node is negative for malignancy
- C. Lymph nodes, periaortic (excision):
- 7 out of 7 lymph nodes are negative for malignancy
- D. Lymph nodes, external iliac (excision):
- 2 out of 2 lymph nodes are negative for malignancy
- E. Lymph node, right obturator (excision):
- 2 out of 2 lymph nodes are negative for malignancy
- F. Lymph nodes, right common iliac (excision):
- 2 out of 2 lymph nodes are negative for malignancy
- G. Lymph nodes, right periaortic lymph node (excision):
- 3 out of 3 lymph nodes are negative for malignancy
- H. Rectovaginal septum (biopsy):
- Fragment of fibrous tissue with microcalcification. Negative for malignancy
- J. Uterus, cervix and ovaries (hysterectomy):
- Squamous cell carcinoma, keratinizing, moderately to poorly

[page 2 of 8]
Name

Loc:

SURGICAL PATHOLOGY

(Continued)

Acct#: [REDACTED] GYNS Adm: [REDACTED]

differentiated (G2-3)

-Tumor infiltrates 10mm in a 15 mm cervical wall.

-Tumor size: Greatest dimension: 4 cm

-Tumor site : 12 to 9 o' clock

-Margins: uninvolved by invasive carcinoma

Distance of invasive carcinoma from closest vaginal margin:
20mm

Koilocytic atypia present within 1mm of vaginal margin

-Lymph-Vascular Invasion: indeterminate

pT1b1 [IB1]: (Clinically visible lesion d4.0 cm in greatest dimension)

pN1: Regional lymph node metastasis

Number examined: 19

Number involved: 2

-Distant Metastasis (pM): not applicable

-Cervical intraepithelial neoplasm III (CIN III)

- Endometrium: proliferative endometrium

- Lower uterine segment: unremarkable

-Ovaries, bilateral: no significant pathologic abnormalities

-Fallopian Tubes, bilateral: endometriosis.

Comment: previous case ([REDACTED]) has been reviewed.

***Electronically Signed Out
M.D.

**

Clinical History

[REDACTED] year-old G3P3, IB1 SCC cervix.

Pre Operative Diagnosis

See clinical history.

Operation Performed

EUA, exploratory laparotomy, modified radical hysterectomy.

Operative Findings

4 cm exophytic lesion central cervix palpable on EUA. Ex-lap -
enlarged pelvic nodes, 2 cm ext iliac node.

[page 3 of 8]
Name

Loc:

SURGICAL PATHOLOGY

(Continued)

Acct#: [REDACTED] GYNS Adm: '

Intraoperative Diagnosis

Frozen Section:

Rectovaginal septum:

- No evidence of malignancy.

M. D.

Gross Description

The specimen is submitted in 9 containers labeled with the name of the patient

Container A is labeled "left external iliac lymph node and obturator". It consists of two lymph nodes, one measuring 4 X 2 cm and the second measuring 1 cm. The cut surface is replaced by whitish tissue. Representative sections of the largest lymph node are submitted in cassette A1. The smallest lymph node is in cassette A2.

Container B is labeled "left common iliac lymph node". It consists of one lymph node, measuring 2 X 1 cm, entirely submitted in cassette B.

Container C is labeled "left periaortic lymph node". It consists of a fragment of fibroadipose tissue, measuring 2 X 1 cm with possible lymph nodes, entirely submitted in cassette C.

Container D is labeled "right external iliac lymph node". It consists of two lymph nodes, one measuring 1.5 and the other measuring 1.3 cm. They are entirely submitted in cassettes D1 and D2.

Container E is labeled "right obturator lymph node". It consists of two lymph nodes, one measuring 1 cm in maximum dimension and the second measuring 2.5 cm in maximum dimension, entirely submitted in cassettes E1 and E2.

Container F is labeled "right common iliac lymph node". It consists of a fragment of adipose tissue, measuring 1.5 X 1 X 1 cm, entirely submitted in cassette F.

Container G is labeled "right periaortic lymph node". It

[page 4 of 8]
Name:

LOC:2

SURGICAL PATHOLOGY

(Continued)

acct#: [REDACTED] GYNS Adm:

consists of a fragment of adipose tissue, measuring 2 X 1.5 X 0.3 cm, entirely submitted in cassette G.

Container H is labeled "rectovaginal septum biopsy" and it is submitted for frozen section diagnosis. It consists of a fragment of tissue, measuring 0.3 cm in maximum dimension, entirely submitted for frozen section diagnosis. The frozen section is resubmitted in cassette H.

Container I is labeled "uterus, cervix and ovaries". It consists of a uterus attached to bilateral adnexa, weighing 230 grams. The uterus measures 7 X 8 X 3 cm. The right fallopian tube measures 2.5 cm and appears amputated from the distal end. The left fallopian tube measures 3 cm and also appears amputated from the distal end that measures 2.5 cm. The right ovary measures 3 X 1.5 X 0.5 cm and the left ovary measures 4 X 1.5 X 1 cm. The cervix is replaced by an exophytic tumor, measuring approximately 4 X 3 cm and occupying grossly from 12 to 9:00 of the cervix. The tumor is within 2 to 2.5 cm from the vaginal margin. The right parametrium is submitted in cassette I1; left parametrium in cassette I2 and I3. Representative sections of anterior vaginal margin are in cassettes I4; from posterior vaginal margin in I5. A representative section of right fallopian tube and right ovary; the ovary appears grossly unremarkable, in cassette I6. The left fallopian tube and representative section of left ovary are in cassette A7. After opening the specimen, the endometrial lining is thick, measuring 0.4 mm. Representative section is submitted in cassettes I8 and I9. Representative section of lower uterine segment in cassette I10. The thickness of the cervix appears to be approximately 1.5 cm. Representative sections of tumor and cervix are in cassette I11. Exophytic tumor in cassettes I12 and I13. Anterior soft tissue radial margin in I14. Posterior soft tissue radial margin in I15. Additional sections of cervix and parametrium in cassettes I16 and I17.

Microscopic Description

Microscopic Examination was performed.

[page 5 of 8]
RESULTS FOR SELECTED GRID CELL, SUMMARY

Ord # = [REDACTED] *ASAP*/RESULTED Collect D/T=

SURGICAL PATHOLOGY

(1 of 1)

Modifiers:

SURGICAL PATHOLOGY:

CoPath Specimen #

Source:

- A: Left External iliac lymph node \T\ obturator
- B: Left Common iliac lymph node
- C: Left Peri-aortic lymph node
- D: Right External iliac lymph node
- E: Right Obturator lymph node
- F: Right Common iliac lymph node
- G: Right Peri-aortic lymph node
- H: Recto-vaginal septum biopsy, (f/s)
- I: Uterus, Cervix \T\ ovaries

Final Diagnosis

- A. Lymph nodes, left external iliac \T\ obturator (excision);
- 2 out of 2 lymph nodes show metastatic squamous cell carcinoma
- Lymph node largest size: 4 cm in maximal dimension
- No evidence of extracapsular invasion
- B. Lymph node, common iliac (excision):
- 1 out of 1 lymph node is negative for malignancy
- C. Lymph nodes, periaortic (excision):
- 7 out of 7 lymph nodes are negative for malignancy
- D. Lymph nodes, external iliac (excision):
- 2 out of 2 lymph nodes are negative for malignancy
- E. Lymph node, right obturator (excision):
- 2 out of 2 lymph nodes are negative for malignancy
- F. Lymph nodes, right common iliac (excision):
- 2 out of 2 lymph nodes are negative for malignancy
- G. Lymph nodes, right periaortic lymph node (excision):
- 3 out of 3 lymph nodes are negative for malignancy
- H. Rectovaginal septum (biopsy):
- Fragment of fibrous tissue with microcalcification. Negative for malignancy
- J. Uterus, cervix and ovaries (hysterectomy):
- Squamous cell carcinoma, keratinizing, moderately to poorly

[page 6 of 8]
Name

Loc :

SURGICAL PATHOLOGY

(Continued)

Acct#: [REDACTED] GYNs Adm: [REDACTED]

differentiated (G2-3)

-Tumor infiltrates 10mm in a 15 mm cervical wall.

-Tumor size: Greatest dimension: 4 cm

-Tumor site : 12 to 9 o' clock

-Margins: uninvolved by invasive carcinoma

Distance of invasive carcinoma from closest vaginal margin:
20mm

Koilocytic atypia present within 1mm of vaginal margin

-Lymph-Vascular Invasion: indeterminate

pT1b1 [IB1]: (Clinically visible lesion d4.0 cm in greatest dimension)

pN1: Regional lymph node metastasis

Number examined: 19

Number involved: 2

-Distant Metastasis (pM): not applicable

-Cervical intraepithelial neoplasm III (CIN III)

- Endometrium: proliferative endometrium

- Lower uterine segment: unremarkable

-Ovaries, bilateral: no significant pathologic abnormalities

-Fallopian Tubes, bilateral: endometriosis.

Comment: previous case (has been reviewed.

***Electronically Signed Out

27, M.D.

Clinical History

year-old G3P3, IB1 SCC cervix.

Pre Operative Diagnosis

See clinical history.

Operation Performed

EUA, exploratory laparotomy, modified radical hysterectomy.

Operative Findings

4 cm exophytic lesion central cervix palpable on EUA. Ex-lap - enlarged pelvic nodes, 2 cm ext iliac node.

[page 7 of 8]
Name:
Loc:

SURGICAL PATHOLOGY

(Continued)

Acct#: [REDACTED] GYNS Adm: _____

Intraoperative Diagnosis
Frozen Section:

Rectovaginal septum:
- No evidence of malignancy.

, M. D.

Gross Description

The specimen is submitted in 9 containers labeled with the name of the patient

Container A is labeled "left external iliac lymph node and obturator". It consists of two lymph nodes, one measuring 4 X 2 cm and the second measuring 1 cm. The cut surface is replaced by whitish tissue. Representative sections of the largest lymph node are submitted in cassette A1. The smallest lymph node is in cassette A2.

Container B is labeled "left common iliac lymph node". It consists of one lymph node, measuring 2 X 1 cm, entirely submitted in cassette B.

Container C is labeled "left periaortic lymph node". It consists of a fragment of fibroadipose tissue, measuring 2 X 1 cm with possible lymph nodes, entirely submitted in cassette C.

Container D is labeled "right external iliac lymph node". It consists of two lymph nodes, one measuring 1.5 and the other measuring 1.3 cm. They are entirely submitted in cassettes D1 and D2.

Container E is labeled "right obturator lymph node". It consists of two lymph nodes, one measuring 1 cm in maximum dimension and the second measuring 2.5 cm in maximum dimension, entirely submitted in cassettes E1 and E2.

Container F is labeled "right common iliac lymph node". It consists of a fragment of adipose tissue, measuring 1.5 X 1 X 1 cm, entirely submitted in cassette F.

Container G is labeled "right periaortic lymph node". It

[page 8 of 8]
Name:

LOC:2

SURGICAL PATHOLOGY

(Continued)

Acct#: [REDACTED] GYNS Adm:

consists of a fragment of adipose tissue, measuring 2 X 1.5 X 0.3 cm, entirely submitted in cassette G.

Container H is labeled "rectovaginal septum biopsy" and it is submitted for frozen section diagnosis. It consists of a fragment of tissue, measuring 0.3 cm in maximum dimension, entirely submitted for frozen section diagnosis. The frozen section is resubmitted in cassette H.

Container I is labeled "uterus, cervix and ovaries". It consists of a uterus attached to bilateral adnexa, weighing 230 grams. The uterus measures 7 X 8 X 3 cm. The right fallopian tube measures 2.5 cm and appears amputated from the distal end. The left fallopian tube measures 3 cm and also appears amputated from the distal end that measures 2.5 cm. The right ovary measures 3 X 1.5 X 0.5 cm and the left ovary measures 4 X 1.5 X 1 cm. The cervix is replaced by an exophytic tumor, measuring approximately 4 X 3 cm and occupying grossly from 12 to 9:00 of the cervix. The tumor is within 2 to 2.5 cm from the vaginal margin. The right parametrium is submitted in cassette I1; left parametrium in cassette I2 and I3. Representative sections of anterior vaginal margin are in cassettes I4; from posterior vaginal margin in I5. A representative section of right fallopian tube and right ovary; the ovary appears grossly unremarkable, in cassette I6. The left fallopian tube and representative section of left ovary are in cassette A7. After opening the specimen, the endometrial lining is thick, measuring 0.4 mm. Representative section is submitted in cassettes I8 and I9. Representative section of lower uterine segment in cassette I10. The thickness of the cervix appears to be approximately 1.5 cm. Representative sections of tumor and cervix are in cassette I11. Exophytic tumor in cassettes I12 and I13. Anterior soft tissue radial margin in I14. Posterior soft tissue radial margin in I15. Additional sections of cervix and parametrium in cassettes I16 and I17.

Microscopic Description

Microscopic Examination was performed.

Source: NCI Genomic Data Commons file a340c53c-104d-42f3-9b8e-8b1ab960cdf9 (TCGA-DS-A1OC.8E48E714-87FA-4B0A-86DB-75E58784AA2C.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).